Surgical pathology report (de-identified scan), TCGA case TCGA-34-8456, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-34-8456-01A (Primary Tumor).

FINAL DIAGNOSIS:**PART 1: LYMPH NODE, LEVEL 9 BETA, BIOPSY –**

ONE (1) BENIGN LYMPH NODE, FREE OF TUMOR.

PART 2: LYMPH NODE, LEVEL 11 BETA, BIOPSY –

ONE (1) BENIGN LYMPH NODE WITH ANTHRACOTIC PIGMENT DEPOSITS, FREE OF TUMOR (0/1).

PART 3: LYMPH NODE, LEVEL 11 EPSILON, BIOPSY –

ONE (1) BENIGN LYMPH NODE WITH ANTHRACOTIC PIGMENT DEPOSIT, FREE OF TUMOR (0/1).

PART 4: LYMPH NODE, RIGHT UPPER LOBE POSTERIOR SEGMENT LEVEL 11 ALPHA, BIOPSY -

ONE (1) BENIGN LYMPH NODE WITH ANTHRACOTIC PIGMENT DEPOSITS, FREE OF TUMOR (0/1).

PART 5: LUNG, RIGHT LOWER LOBE, LOBECTOMY –

A. INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA WITH FOCAL BASALOID AND CLEAR CELL FEATURES AND FOCAL NECROSIS (3.6 X 3.5 X 3.5 CM) (SEE COMMENT).

B. LYMPHOVASCULAR INVASION IS PRESENT.

C. NEGATIVE FOR PLEURAL INVASION. (PLO).

D. BRONCHIAL MARGIN OF RESECTION WITH SMALL TUMOR CLUSTER IN A VESSEL (SEE COMMENT).

E. OBSTRUCTIVE PNEUMONITIS.

F. FOCAL EMPHYSEMATOUS CHANGES AND INTERALVEOLAR FIBROSIS.

G. METASTATIC SQUAMOUS CELL CARCINOMA IN THREE OF NINE (3/9) PERIHILAR LYMPH NODES WITH FOCAL EXTRANODAL TUMOR EXTENSION.

H. AJCC [REDACTED] TNM STAGE: pT2a N1.

PART 6: LYMPH NODE, LEVEL 4, BIOPSY –

ONE (1) BENIGN LYMPH NODE, FREE OF TUMOR (0/1).

PART 7: LYMPH NODE, LEVEL 7, BIOPSY –

ONE (1) BENIGN LYMPH NODE WITH ANTHRACOTIC PIGMENT DEPOSITS, FREE OF TUMOR (0/1).

PART 8: AZYGOS, RESECTION –

PORTION OF VESSEL, SMALL NERVE FASCICLES AND FIBROADIPOSE TISSUE, FREE OF TUMOR.

COMMENT:

The neoplasm is subpleural and peripheral, located grossly at 6.5 cm. from the bronchial and vascular margins of resection. Microscopic examination of the margin shows a small cluster of tumor cells in a vessel.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY LUNG TUMORS****TUMOR LOCATION:**

Right Lower Lobe

PROCEDURE:

Lobectomy

TUMOR SIZE:

Maximum dimension: 3.6 cm

Minor dimension: 3.5 cm

GROSS SATELLITES:

Number of gross satellite lesions: 0

TUMOR TYPE:

Invasive squamous carcinoma, peripheral type

HISTOLOGIC GRADE:

G2, Moderately differentiated

EXTRAPULMONARY EXTENSION/INVASION OF TUMOR:

None identified (PLO)

ANGIOLYMPHATIC INVASION:

Yes

TUMOR NECROSIS:

< or = to 50%

SURGICAL MARGIN INVOLVEMENT:

Yes

SURGICAL MARGIN SITE:

Bronchial margin

INFLAMMATORY(DESMOPLASTIC) REACTION:

Moderate

N1 LYMPH NODES:

Number of N1 lymph nodes positive: 3

Number of N1 lymph nodes examined: 12

EXTRACAPSULAR SPREAD OF N1 METASTASES:

Yes

N2 LYMPH NODES:

Number of N2 lymph nodes positive: 0

Number of N2 lymph nodes examined: 3

UNDERLYING DISEASE(S):

Emphysema, Obstructive pneumonia, focal

T STAGE, PATHOLOGIC:

pT2a

N STAGE, PATHOLOGIC:

pN1

M STAGE, PATHOLOGIC:

Not applicable

ANCILLARY STUDIES:

Histochemical stains, Molecular studies

Comment:

The bronchial margin of resection shows a small tumor cluster in a vessel

Source: NCI Genomic Data Commons file 7f37d503-3b1d-432b-aad6-dd5e4a0e1283 (TCGA-34-8456.650C7AD8-13AA-487B-922D-373E4E556054.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).